Gene-level copy-number profile of tumor specimen TCGA-D8-A1JN-01A from TCGA case TCGA-D8-A1JN, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 80.3 years (29,331 days).
Specimen TCGA-D8-A1JN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.501e2d9b-703f-4ca0-95f6-bcf0267d1a32.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D8-A1JN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/663be517-1f82-4d7b-9021-1cc630bd21fe

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,267; copy number 2: 49,927; copy number 3: 2,623; copy number 5: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D8-A1JN-01A-11D-A13J-01): tumor purity 0.94, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:91,603,275–91,904,335, 3 genes, copy number 5: AC110774.1, KRT19P6, AC093810.1.

Autosomal genes at a single copy (total copy number 1): 7,267. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
